Surgical pathology report (de-identified scan), TCGA case TCGA-31-1959, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1959-01A (Primary Tumor).

[page 1 of 2]
Specimen Type:

A: RIGHT OVARY AND UTERUS
B: LEFT OVARY
C: Omentum
D: ANTERIOR ABDOMINAL WALL NODE

TCGA-31-1959

Clinical Details:

Ovarian Debulking.

Macroscopic Description:

A) RIGHT OVARY AND UTERUS: The ovary weighs 53.3 grams and measures 6.5 x 5.5 x 4.5 cm. The ovarian cyst wall is ruptured. The cut surface shows a multilocular cyst with solid areas. The solid area shows tan coloured and brownish areas. The uterus corpus measures 6 cm longitudinally, 3 cm transversally and 3.2 cm anteroposteriorly. The fallopian tubes are not included.

BLOCKS: A1 to A8 – 1 pc in each, rep sections from right ovarian tumour
A9 and A10 – 1 pc in each, lower uterine segment
A11 to A14 – 1 pc in each, endomyometrium with rep sections.

B) LEFT OVARY: The ovary measures 2.5 x 1.5 x 0.8 cm. The fallopian tube measures 5.2 cm and the maximum diameter measures 0.6 cm.

BLOCKS: B1 and B2 – 1 pc in each, left ovary bisected
B3 – 3 pcs, fallopian tube with rep sections.

C) OMENTUM: A piece of omentum measuring 28 x 8 x 1.2 cm. There are two nodular areas each measuring 6.5 x 4.5 x 1.5 cm and 7.5 x 4 x 1.3 cm. The cut surface of the nodules shows tan coloured homogenous.

BLOCKS: C1 to C7 – 1 pc in each, rep sections from nodular areas.

[page 2 of 2]
D) ANTERIOR ABDOMINAL NODULE WALL: A piece of fibro-fatty tissue measuring 7 x 4.5 x 1.5 cm.

BLOCKS: D1 – 3 pcs
D2 – 2 pcs
D3 to D5 – 1 pc in each, rep sections from nodule
D6 – 3 pcs, rep sections from nodule

TCGA-31-1959

Microscopic Description:

A) RIGHT OVARY AND UTERUS: The ovarian neoplasm is serous carcinoma, Grade II-III. The tumour cells are arranged in sheets, tubulopapillary formations and lining cystic spaces. The cells have enlarged vesicular nuclei with conspicuous nucleoli. The tumour invades peri adnexal tissue investing the fallopian tube. Mitoses are frequent psammoma bodies are focally seen. There is focal blood vessels invasion (Block A5). No features of dysplasia or malignancy are seen in the fallopian tube mucosa.

The cervix contains Nabothian cysts. The endometrium is inactive and the cells focally show ciliated and eosinophilic metaplasia. Deposits of serous carcinoma are present within lymphatics in the myometrium and focally seen invading the myometrium (Block A13).

B) LEFT OVARY: The peri adnexal tissue is extensively infiltrated by tumour tissue similar to that seen in the right ovary. Tumour deposits are present in the ovarian parenchyma. Detached tumour fragments are present in the lumen of the fallopian tube. However, the tubal epithelium shows no features of dysplasia or malignancy.

C) OMENTUM: The omentum is extensively infiltrated by tumour.

D) ANTERIOR ABDOMINAL WALL NODULE: Multiple representative sections examined show fibrofatty tissue infiltrated by serous carcinoma. Tumour cells extend very close to the cauterized margin.

The tumour cells express PgR (Allred's score 2) and ER (Allred's score 5).

Final Diagnosis:

A AND B) UTERUS, TUBES & OVARIES: BILATERAL OVARIAN SEROUS CARCINOMA,
GRADE II-III, STAGE IV

C) OMENTUM: METASTATIC SEROUS CARCINOMA

D) ANTERIOR ABDOMINAL WALL NODULE: METASTATIC SEROUS CARCINOMA

Additional Pathologist(s)/BMS(s)

Source: NCI Genomic Data Commons file e5a66c80-788f-475d-a6be-be726a6807fe (TCGA-31-1959.C78C6998-1F86-4DD2-BF41-78F12D43C33A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).